CPTAC case C3N-00953 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1570eaf1-9b92-4506-9df0-9ae9a704a731

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1975; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 41.4 years (15,137 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,785 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,785 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 333 days; Disease response: Tumor Free.
- Days to follow up: 685 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,051 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,428 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,428 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,785 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 77.11 kg; Height: 185.42 cm; BMI: 22.43.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00953-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 155 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00953-21: Section location: Upper pole; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3N-00953-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 252 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00953-22: Section location: Upper pole; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-00953-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 193 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00953-23: Section location: Upper pole; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-00953-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3N-00953-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
